Somatic mutation profile of tumor specimen TCGA-MJ-A68J-01A (aliquot TCGA-MJ-A68J-01A-11D-A307-09) from TCGA case TCGA-MJ-A68J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 55.0 years (20,100 days).
Specimen TCGA-MJ-A68J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7827148b-2ba0-4afd-a370-cd50ff1bc7bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MJ-A68J-10A (Blood Derived Normal), aliquot TCGA-MJ-A68J-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/031fc074-8a76-4090-85f4-6d5f87e98d39

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV99591867; called by muse, mutect2, varscan2
- BCL6 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99216050; called by muse, mutect2
- C2orf16 | c.4963C>A p.R1655S | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100821014; called by muse, mutect2, varscan2
- CARD11 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs141751925, COSV101210414, COSV67802575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR6C76 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); catalogued as rs776778880, COSV60389832; called by muse, mutect2
- RPL36A | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1555983461, COSV65717964; called by muse, mutect2, varscan2
- SPG11 | c.5359G>T p.D1787Y | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1185283884, COSV99969622; called by muse, mutect2, varscan2
- SYT2 | c.510C>G p.D170E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100937203; called by muse, mutect2, varscan2
- TUBGCP5 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABCC6 | c.3975C>T p.I1325= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs751220009, COSV99228842; called by muse, mutect2, varscan2
- ISM1 | c.1050C>T p.D350= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs572363345, COSV52603697; called by muse, mutect2, varscan2
- SLC27A6 | c.354C>T p.F118= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs1372634243, COSV52479372; called by muse, mutect2, varscan2
